Somatic mutation profile of tumor specimen ALCH-B2FP-TTP1-A (aliquot ALCH-B2FP-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2FP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.2 years (25,658 days).
Specimen ALCH-B2FP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a9f265b-81d4-4e76-9b67-843b76a8211f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2FP-NB1-A (Blood Derived Normal), aliquot ALCH-B2FP-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35242c67-2b12-4590-89ee-477d1c2e9409

The open-access MAF lists 937 somatic variants for this specimen: 650 protein-altering or splice-affecting, 178 silent, 109 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 551, Silent 178, Nonsense Mutation 50, Intron 46, Splice Site 22, RNA 18, 3'UTR 17, 5'UTR 15, Frame Shift Del 12, 5'Flank 10, Splice Region 9, Frame Shift Ins 4.

Variants (750 of 937; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 14/457 reads (3%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as rs1048095040, CM100445, CM951235, COSV52848377, COSV53866546; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- AC136428.1 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 67/447 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as COSV101434972; called by muse, mutect2, varscan2
- ADAMTS12 | c.1447G>T p.G483* | Nonsense Mutation (SNP) | VAF 39/140 reads (28%) | catalogued as COSV61262255; called by muse, mutect2, varscan2
- ADAMTS20 | c.4465T>C p.C1489R | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV101240727; called by muse, mutect2
- ADGRG4 | c.7585G>T p.A2529S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV54966394; called by muse, mutect2
- AL162417.1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs763509041; called by muse, mutect2, varscan2
- ALDH1L1 | c.1445C>A p.A482E | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs781455179; called by muse, mutect2, varscan2
- ANKK1 | c.1162G>T p.V388L | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as COSV100392876; called by muse, mutect2, varscan2
- ANKRD30B | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 24/126 reads (19%) | catalogued as rs767362328; called by muse, varscan2
- ANOS1 | c.2003G>T p.R668L | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.046); catalogued as COSV52927509; called by muse, mutect2, varscan2
- APCDD1 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV62372072; called by muse, mutect2, varscan2
- ARHGAP32 | c.4934G>A p.R1645Q (on ENST00000310343 / NM_001378025.1; = p.R1296Q on NM_014715.4) | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758198053, COSV100088532; called by muse, mutect2
- ARMCX1 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.444); catalogued as rs782427731; called by muse, mutect2, varscan2
- ASB15 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV104369504; called by muse, mutect2, varscan2
- ASB18 | c.983C>A p.S328* | Nonsense Mutation (SNP) | VAF 20/127 reads (16%) | catalogued as rs1292548272; called by muse, mutect2, varscan2
- ASCL1 | c.529C>A p.H177N | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV57151132; called by muse, mutect2, varscan2
- ASTN1 | c.1445G>A p.C482Y | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56070458; called by muse, mutect2, varscan2
- ASXL3 | c.3107G>T p.R1036L | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs776506817, COSV52473460; called by muse, mutect2, varscan2
- ATAD3C | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 11/241 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV66482113; called by muse, mutect2
- ATP11C | c.2593C>G p.H865D | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59574063; called by muse, mutect2
- ATP1A2 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs767672945; called by muse, mutect2, varscan2
- ATP8A2 | c.892-1G>T p.X298_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV54943474; called by muse, mutect2
- AVPR2 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 52/144 reads (36%) | catalogued as CM940159, COSV61686520; called by muse, mutect2, varscan2
- BAZ1A | c.3658G>C p.D1220H | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.068); catalogued as COSV62410914; called by muse, mutect2
- BCHE | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV52261249; called by muse, mutect2, varscan2
- BCORL1 | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54403527; called by muse, mutect2, varscan2
- BOD1L1 | c.8557G>C p.E2853Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV50043969; called by muse, mutect2
- BRAF | c.1861A>T p.N621Y (on ENST00000288602 / NM_001374244.1; = p.N581Y on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as CM060878, COSV56062673, COSV56077649, COSV56286119; called by muse, mutect2, varscan2
- BRWD3 | c.4462C>A p.H1488N | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV64750342; called by muse, mutect2, varscan2
- BTBD11 | c.2168G>A p.G723E (on ENST00000280758 / NM_001018072.2; = p.G260E on NM_001017523.2) | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55021625; called by muse, mutect2
- C11orf65 | c.81+1G>T p.X27_splice | Splice Site (SNP) | VAF 49/273 reads (18%) | catalogued as rs755091353; called by muse, mutect2, varscan2
- CACNA1E | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100702228; called by muse, mutect2, varscan2
- CACNA2D4 | c.1600G>T p.D534Y | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764192200; called by muse, mutect2, varscan2
- CCDC88B | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1012242165; called by muse, mutect2, varscan2
- CDH9 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50253684, COSV50434304; called by muse, mutect2, varscan2
- CHD7 | c.5030G>T p.R1677L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as CX129961; called by muse, mutect2, varscan2
- CHGB | c.1157A>G p.K386R | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.104); catalogued as rs1461940095; called by muse, mutect2, varscan2
- CHRM2 | c.964C>G p.Q322E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57783972; called by muse, mutect2, varscan2
- CHRM3 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs202097685, COSV55093350, COSV99697259; called by muse, mutect2, varscan2
- CNTN6 | c.2558G>T p.G853V | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); catalogued as COSV63187251; called by muse, mutect2, varscan2
- CNTNAP4 | c.1925C>A p.T642K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs773855844; called by muse, mutect2, varscan2
- CNTNAP5 | c.2134G>A p.G712S | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs1431647216; called by muse, mutect2
- COL11A1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 37/372 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.309); catalogued as COSV62171221; called by muse, mutect2
- COL3A1 | c.2264C>A p.P755Q | Missense Mutation (SNP) | VAF 62/378 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1553508711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.2049G>T p.T683= | Splice Region (SNP) | VAF 5/52 reads (10%) | catalogued as COSV100094956; called by mutect2, varscan2
- COLEC12 | c.459G>C p.L153F | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1343043498; called by muse, mutect2
- CRB1 | c.4126C>A p.Q1376K | Missense Mutation (SNP) | VAF 129/559 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV66348663; called by muse, mutect2, varscan2
- CRISP1 | c.-2G>T | Splice Region (SNP) | VAF 26/161 reads (16%) | catalogued as COSV100237102; called by muse, mutect2, varscan2
- CSMD3 | c.4789G>T p.G1597C (on ENST00000297405 / NM_001363185.1; = p.G1493C on NM_052900.3) | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99839584; called by muse, mutect2
- CTIF | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 72/364 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1428809381; called by muse, mutect2, varscan2
- DACH2 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as rs1361685637, COSV64181231; called by muse, mutect2, varscan2
- DCAF12L1 | c.1250G>A p.W417* | Nonsense Mutation (SNP) | VAF 29/186 reads (16%) | catalogued as COSV64422012; called by muse, mutect2, varscan2
- DCAF12L2 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1189337078; called by muse, mutect2, varscan2
- DDX11 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 74/544 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.638); catalogued as rs753593451, COSV52503370; called by muse, mutect2, varscan2
- DLX6 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 42/427 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs530888638, COSV50293438; called by muse, mutect2
- DMBX1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63602083; called by muse, varscan2
- DNAH11 | c.1503T>A p.N501K | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV60945941; called by muse, mutect2, varscan2
- DSCAM | c.4850G>T p.R1617L | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101260907; called by muse, mutect2, varscan2
- EHMT1 | c.3646C>T p.H1216Y | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs569375203; called by muse, mutect2
- ELANE | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs201313263, COSV55047716; ClinVar: uncertain significance; called by muse, mutect2
- ERC1 | c.2337A>G p.I779M (on ENST00000360905 / NM_178040.4; = p.I751M on NM_178039.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780998272; called by muse, mutect2, varscan2
- EXT1 | c.1723G>T p.V575L | Missense Mutation (SNP) | VAF 71/387 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.364); catalogued as CS063300, COSV100984062; called by muse, mutect2, varscan2
- EYS | c.5413C>A p.Q1805K | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.212); catalogued as COSV58201209; called by muse, mutect2, varscan2
- FAH | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs762404387, CM119756, COSV99930395; called by muse, mutect2, varscan2
- FAM102A | c.592G>T p.A198S (on ENST00000373095 / NM_001035254.3; = p.A56S on NM_203305.2) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs989142718; called by muse, varscan2
- FAM47A | c.2107A>G p.K703E | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV60498444; called by muse, mutect2, varscan2
- FARP1 | c.2938G>T p.G980C | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200545303; called by muse, mutect2, varscan2
- FASLG | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.377); catalogued as COSV60679822; called by muse, mutect2
- FEM1A | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416347610; called by muse, mutect2
- FLT1 | c.1127C>A p.A376E | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs757020625, COSV56727272; called by muse, mutect2, varscan2
- FSIP2 | c.18898C>A p.P6300T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100554757; called by muse, mutect2, varscan2
- FSTL5 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100059628; called by muse, mutect2, varscan2
- GRIA2 | c.2190C>A p.N730K | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52411809; called by muse, mutect2, varscan2
- GRID2IP | c.2026A>C p.S676R | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs1294023041; called by muse, mutect2, varscan2
- GRM5 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.49); catalogued as COSV100555021, COSV59605587; called by muse, mutect2, varscan2
- GSPT2 | c.879T>G p.S293R | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61214809; called by muse, mutect2
- HCN4 | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99983529; called by muse, mutect2, varscan2
- HCN4 | c.1231C>A p.L411M | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1264460587; called by muse, mutect2, varscan2
- HECW2 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.85); catalogued as rs765958118, COSV53666048; called by muse, mutect2
- HOXD13 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs773346852; called by muse, mutect2
- HRNR | c.1183C>A p.R395S | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs144722087; called by muse, mutect2, varscan2
- HUWE1 | c.9358G>T p.A3120S | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV53342108; called by muse, mutect2, varscan2
- IGLON5 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV54536011; called by muse, mutect2, varscan2
- IREB2 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs772637326; called by muse, mutect2, varscan2
- IRS1 | c.700G>T p.G234W | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59335233; called by muse, mutect2, varscan2
- IRS4 | c.1581G>T p.Q527H | Missense Mutation (SNP) | VAF 76/432 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV64535878; called by muse, mutect2, varscan2
- ITSN1 | c.1811A>G p.N604S | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1003851448; called by muse, mutect2, varscan2
- KIF4B | c.1181C>A p.S394Y | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs1370856200, COSV70528775; called by muse, mutect2
- KIF4B | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV70531376; called by muse, mutect2
- KLHDC7A | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs375012792; called by mutect2, varscan2
- KMT2D | c.14897G>T p.R4966L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV56465455; called by muse, mutect2, varscan2
- KPRP | c.1364G>T p.C455F | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100908655, COSV64222934; called by muse, mutect2, varscan2
- KSR2 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779409612, COSV56673016; called by muse, mutect2, varscan2
- LAMC3 | c.3703G>T p.V1235L | Missense Mutation (SNP) | VAF 74/333 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as CM1514111, COSV62655475; called by muse, mutect2, varscan2
- LCT | c.3607G>T p.V1203F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.934); catalogued as COSV51547245; called by muse, mutect2, varscan2
- LOXHD1 | c.1442C>A p.P481Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs373604796; called by muse, mutect2, varscan2
- LRRC4B | c.882C>A p.H294Q | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV65349545; called by muse, mutect2, varscan2
- LRRC66 | c.2396C>A p.S799Y | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58636188; called by muse, mutect2, varscan2
- LRRC7 | c.359C>A p.S120* (on ENST00000651989 / NM_001370785.2; = p.S87* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/170 reads (5%) | catalogued as COSV99223856; called by muse, mutect2
- LY6H | c.373G>T p.G125W | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs537176820, COSV100713907, COSV61370775; called by muse, mutect2, varscan2
- MAMLD1 | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs782079053; called by muse, mutect2, varscan2
- MASTL | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV60911820; called by muse, mutect2
- MEX3D | c.1726del p.L576Wfs*33 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs1487685986; called by mutect2, pindel
- MGA | c.3658-2A>T p.X1220_splice | Splice Site (SNP) | VAF 15/100 reads (15%) | catalogued as COSV54951099; called by muse, varscan2
- MIA3 | c.1613G>C p.G538A | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV60510369; called by muse, mutect2
- MLLT3 | c.994C>G p.H332D | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV63497204; called by muse, mutect2
- MMEL1 | c.779C>A p.S260Y | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56526198; called by muse, mutect2, varscan2
- MTERF2 | c.921G>C p.L307F | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53528692, COSV53528816; called by muse, mutect2
- MUC2 | c.1933A>G p.M645V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1223758691; called by muse, mutect2, varscan2
- MYH2 | c.4742A>G p.K1581R | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV55437662; called by muse, mutect2
- MYH7 | c.4118C>A p.T1373N | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV62518349; called by muse, varscan2
- NAA25 | c.843G>T p.W281C | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99927155; called by muse, mutect2, varscan2
- NCAPD3 | c.4277G>C p.G1426A | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs1198030652; called by muse, mutect2
- NCOR1 | c.6337C>T p.Q2113* | Nonsense Mutation (SNP) | VAF 102/419 reads (24%) | catalogued as COSV52000071; called by muse, mutect2, varscan2
- NEMP1 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 27/126 reads (21%) | catalogued as COSV104411177; called by muse, mutect2, varscan2
- NLRP12 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 94/474 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60743904; called by mutect2, varscan2
- NTF3 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV58417164; called by muse, mutect2, varscan2
- OAZ1 | c.465-1G>T p.X155_splice | Splice Site (SNP) | VAF 11/87 reads (13%) | catalogued as rs1423079365; called by muse, mutect2, varscan2
- OLFM1 | c.739G>C p.G247R (on ENST00000371793 / NM_001282611.2; = p.G229R on NM_014279.5) | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53281234; called by muse, mutect2, varscan2
- OR10A5 | c.786G>T p.W262C | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV55054502; called by muse, mutect2, varscan2
- OR11H1 | c.623C>A p.S208* | Nonsense Mutation (SNP) | VAF 60/405 reads (15%) | catalogued as COSV99421708, COSV99421741; called by muse, mutect2, varscan2
- OR2A2 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68872784; called by muse, mutect2, varscan2
- OR51E1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142449769, COSV67810348; called by muse, mutect2
- OR5D14 | c.602T>A p.L201H | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV59455376; called by muse, mutect2
- OR6K3 | c.258G>T p.E86D (on ENST00000368146; = p.E70D on NM_001005327.2) | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1427638497, COSV63746602; called by muse, mutect2, varscan2
- PARVA | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1216380128, COSV104404603; called by muse, mutect2, varscan2
- PBRM1 | c.3685A>G p.I1229V (on ENST00000296302 / NM_001366071.2; = p.I1204V on NM_018313.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.217); catalogued as COSV99970062; called by muse, mutect2, varscan2
- PCDHA5 | c.2105C>A p.A702D | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV65350514; called by muse, mutect2, varscan2
- PEPD | c.706A>T p.M236L | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV54889819; called by muse, mutect2, varscan2
- PIM2 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as rs374259559; called by muse, mutect2, varscan2
- PLPPR4 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as rs772461989; called by muse, mutect2
- PLXNA4 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs375715133; called by muse, mutect2, varscan2
- PMCH | c.161C>A p.A54E | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100268183; called by muse, mutect2
- PNMA8B | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs1326197331, COSV66536915; called by muse, mutect2, varscan2
- POLN | c.2168G>T p.R723L | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs141418933; called by muse, mutect2, varscan2
- PPP1R12B | c.2911G>T p.G971C | Missense Mutation (SNP) | VAF 17/284 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs1040525086; called by muse, mutect2
- PREX1 | c.294C>G p.V98= | Splice Region (SNP) | VAF 13/60 reads (22%) | catalogued as COSV64256784; called by muse, mutect2, varscan2
- PRKCB | c.1555G>T p.G519W | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100331981; called by muse, mutect2, varscan2
- PROC | c.962C>A p.P321Q | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM930618, COSV99300779; called by muse, mutect2, varscan2
- PSG3 | c.679C>A p.R227S | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV59504606; called by muse, mutect2
- PSG3 | c.678C>A p.S226R | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.942); catalogued as COSV100548812; called by muse, mutect2
- PTCHD4 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs777537625, COSV59776521; called by muse, mutect2
- PXDN | c.2519G>T p.R840L | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs746533208; called by mutect2, varscan2
- RAI14 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV99464748; called by muse, mutect2, varscan2
- RALGAPA2 | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs6112939; called by muse, mutect2
- RASAL3 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs772292750; called by muse, mutect2, varscan2
- RBL1 | c.2701G>A p.D901N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1219721449; called by muse, mutect2
- RELN | c.938T>A p.L313H | Missense Mutation (SNP) | VAF 21/341 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99067104; called by muse, mutect2
- RHPN1 | c.1625G>T p.S542I | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV56646175; called by muse, mutect2, varscan2
- RNF175 | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as rs776559879, COSV56841411; called by muse, mutect2, varscan2
- RPL26 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV53446831; called by muse, mutect2
- RTP1 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as COSV56618008; called by muse, mutect2, varscan2
- RXFP3 | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs757382584; called by muse, mutect2, varscan2
- SAMSN1 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 25/211 reads (12%) | catalogued as COSV53470051; called by muse, mutect2, varscan2
- SEMA3A | c.1610G>T p.W537L | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54862279; called by muse, mutect2, varscan2
- SHC4 | c.461G>T p.R154M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.155); catalogued as rs758870725; called by muse, mutect2, varscan2
- SIGLEC5 | c.1577C>A p.S526Y | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55777679, COSV55783708; called by muse, mutect2, varscan2
- SLC17A6 | c.1517C>A p.A506E | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764346080, COSV54142368; called by muse, mutect2, varscan2
- SLC25A3 | c.818-3C>T | Splice Region (SNP) | VAF 34/422 reads (8%) | catalogued as rs112837620, COSV51845408; called by muse, mutect2
- SLC2A2 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100049480, COSV58585069; called by muse, mutect2, varscan2
- SLC6A15 | c.1922G>T p.R641L | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.072); catalogued as rs778180371, COSV57025857; called by muse, mutect2, varscan2
- SLC6A3 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs751986313, COSV54366459; called by muse, mutect2
- SNX33 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs367776246; called by mutect2, varscan2
- SOX13 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV99690013; called by muse, mutect2
- SPARC | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV50560845; called by muse, mutect2, varscan2
- SPATA3 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs1283373321; called by muse, mutect2, varscan2
- SPEG | c.7637G>A p.R2546H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750554809, COSV56663443, COSV56671445; called by muse, mutect2, varscan2
- SSUH2 | c.74G>T p.R25M | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.173); catalogued as rs778003039; called by muse, mutect2, varscan2
- STX2 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99892479; called by muse, mutect2, varscan2
- SVIL | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs373559551; called by muse, mutect2, varscan2
- TACR3 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1195516345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TADA1 | c.436C>G p.P146A | Missense Mutation (SNP) | VAF 17/477 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV63309948; called by muse, mutect2
- TBC1D1 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs746844362; called by muse, mutect2, varscan2
- TCF21 | c.365G>T p.R122M | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52818032; called by muse, mutect2, varscan2
- TCF25 | c.413G>C p.S138T | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1177061283; called by muse, varscan2
- TDRD5 | c.2512G>T p.D838Y | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV99676608; called by muse, mutect2, varscan2
- TENM4 | c.5716G>T p.E1906* | Nonsense Mutation (SNP) | VAF 50/203 reads (25%) | catalogued as COSV53604493; called by muse, mutect2, varscan2
- TET3 | c.4708G>A p.A1570T | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs562883064, COSV69641658, COSV69644775; called by muse, mutect2
- TGOLN2 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs758707065; called by muse, mutect2
- TM9SF4 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770747344; called by muse, mutect2, varscan2
- TMCC1 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61438612; called by muse, mutect2, varscan2
- TMEM131L | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs377559669; called by muse, mutect2
- TMEM151B | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101441995; called by muse, mutect2
- TNFAIP2 | c.1665del p.N556Mfs*57 | Frame Shift Del (DEL) | VAF 42/158 reads (27%) | catalogued as COSV99070451; called by mutect2, pindel, varscan2
- TPTE | c.894G>T p.R298S (on ENST00000618007 / NM_199261.4; = p.R280S on NM_199259.4) | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs777956432; called by muse, mutect2
- TRAPPC10 | c.1039-1G>T p.X347_splice | Splice Site (SNP) | VAF 14/128 reads (11%) | catalogued as COSV52381838; called by muse, mutect2
- TRBV23-1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1461304872; called by muse, mutect2
- TRGV3 | c.190C>A p.R64S | Missense Mutation (SNP) | VAF 82/519 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as rs779670853; called by mutect2, varscan2
- TRIO | c.5797G>T p.D1933Y | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV60092703; called by muse, mutect2, varscan2
- TRMT13 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.239); catalogued as rs779285219; called by muse, mutect2
- UBR4 | c.12607C>T p.R4203W | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs750472517; called by muse, mutect2, varscan2
- UMOD | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 43/397 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs764920019; called by muse, mutect2, varscan2
- UNC80 | c.8929A>G p.I2977V | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs891223670, COSV55904981; called by muse, mutect2
- USP18 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1168005972; called by muse, mutect2, varscan2
- WASHC4 | c.2389C>T p.L797F | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.045); catalogued as rs1029962492; called by muse, mutect2
- WDFY3 | c.6250C>T p.Q2084* | Nonsense Mutation (SNP) | VAF 34/225 reads (15%) | catalogued as COSV99882425; called by muse, mutect2, varscan2
- WWC3 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 62/367 reads (17%) | catalogued as COSV66503480; called by muse, mutect2, varscan2
- ZAN | c.5122G>T p.A1708S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as rs371235933; called by muse, mutect2
- ZNF385D | c.277-1G>T p.X93_splice | Splice Site (SNP) | VAF 22/96 reads (23%) | catalogued as COSV55780810; called by muse, mutect2, varscan2
- ZNF418 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV68675836; called by muse, varscan2
- ZNF431 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100218876; called by muse, mutect2, varscan2
- ZNF469 | c.4362C>A p.F1454L (on ENST00000437464; = p.F1482L on NM_001367624.2) | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748790994, COSV71259361; called by muse, mutect2, varscan2
- ZNF609 | c.1743C>G p.S581R | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs200880859; called by muse, mutect2, varscan2
- ZNF716 | c.1073G>C p.G358A | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV101348474; called by muse, mutect2, varscan2
- ABCA13 | c.9320A>T p.K3107M | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ABCB4 | c.3228C>A p.S1076R | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCC11 | c.2021A>T p.E674V | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ABCC4 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCD2 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- AC098582.1 | c.2089C>T p.H697Y | Missense Mutation (SNP) | VAF 25/373 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.246); called by muse, mutect2
- AC122719.2 | n.153G>T | Splice Region (SNP) | VAF 57/190 reads (30%) | called by muse, mutect2, varscan2
- AC231657.3 | c.522-2A>G p.X174_splice | Splice Site (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2
- ACE2 | c.439+1G>A p.X147_splice | Splice Site (SNP) | VAF 14/84 reads (17%) | called by muse, varscan2
- ACOX3 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ACTN1 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- ADAM19 | c.2325G>T p.K775N | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ADAMTS10 | c.2411C>A p.A804D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.35); called by muse, mutect2
- ADAMTS14 | c.2563A>T p.S855C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4755-1G>T p.X1585_splice | Splice Site (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- ADGRA1 | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ADGRD2 | c.2469T>A p.N823K | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ADGRF5 | c.3379C>A p.Q1127K | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ADGRL1 | c.588C>A p.Y196* (on ENST00000340736 / NM_001008701.3; = p.Y191* on NM_014921.5) | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- ADH1A | c.318C>G p.N106K | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AFF2 | c.3391G>T p.V1131L | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AGAP9 | c.1933G>A p.G645R | Missense Mutation (SNP) | VAF 17/427 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.448); called by muse, mutect2
- AGPAT3 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP13 | c.3065C>A p.A1022E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- AKR1B10 | c.742-8C>T | Splice Region (SNP) | VAF 37/347 reads (11%) | called by muse, mutect2, varscan2
- ANKRD24 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ANKRD52 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ANO5 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- AOC1 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AOC1 | c.1468T>A p.Y490N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- AP4E1 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 39/215 reads (18%) | called by muse, mutect2, varscan2
- APOB | c.2997C>A p.T999= | Splice Region (SNP) | VAF 34/332 reads (10%) | called by muse, mutect2
- AQP11 | c.588_599del p.A197_I200del | In Frame Del (DEL) | VAF 10/74 reads (14%) | called by mutect2, pindel
- ARHGAP15 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ARHGAP6 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF6 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 58/365 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ARHGEF6 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ARMCX2 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ASCC3 | c.2185G>T p.V729L | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ASTN2 | c.2606G>T p.S869I (on ENST00000313400 / NM_001365069.1; = p.S818I on NM_014010.5) | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP6V1D | c.659T>G p.L220W | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- ATP7B | c.2439A>C p.L813F | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ATRX | c.1592A>C p.N531T | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- B4GALNT4 | c.1837A>T p.T613S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCAM | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BCLAF3 | c.1044C>G p.D348E | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BEND4 | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- BICDL1 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); called by muse, mutect2
- BMPR1B | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- BTBD8 | c.3325G>C p.D1109H (on ENST00000636805 / NM_001376131.1; = p.D596H on NM_015237.4) | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2
- BTBD8 | c.4015G>A p.D1339N (on ENST00000636805 / NM_001376131.1; = p.D826N on NM_015237.4) | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C11orf49 | c.366-1G>T p.X122_splice | Splice Site (SNP) | VAF 31/177 reads (18%) | called by muse, mutect2, varscan2
- C11orf87 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- C19orf84 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- C2CD3 | c.5843C>A p.S1948Y | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C3 | c.3025G>T p.G1009C | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C3orf56 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CCT8L2 | c.788G>C p.S263T | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CD164 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD180 | c.145del p.D49Tfs*29 | Frame Shift Del (DEL) | VAF 23/128 reads (18%) | called by mutect2, varscan2
- CDH6 | c.2357G>T p.S786I | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- CEP164 | c.1488G>C p.Q496H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CEP170 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- CEP250 | c.5147C>T p.P1716L | Missense Mutation (SNP) | VAF 54/345 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CFAP47 | c.681G>T p.E227D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP47 | c.4435G>T p.A1479S | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CHD5 | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHPT1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.439); called by muse, mutect2
- CLIC2 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 28/308 reads (9%) | called by muse, mutect2
- CLIC4 | c.398G>T p.R133M | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- CMTM6 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNGA2 | c.1388T>A p.L463Q | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTNAP3 | c.1994A>G p.Q665R | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CNTNAP5 | c.2135G>A p.G712D | Missense Mutation (SNP) | VAF 25/262 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- COL28A1 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL4A5 | c.4504G>A p.D1502N | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL9A1 | c.1552G>C p.D518H | Missense Mutation (SNP) | VAF 42/433 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, varscan2
- COL9A3 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CPA6 | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2
- CPAMD8 | c.4827-2A>T p.X1609_splice (on ENST00000651564; = p.X1562_splice on NM_015692.5) | Splice Site (SNP) | VAF 38/205 reads (19%) | called by muse, mutect2, varscan2
- CPS1 | c.4225G>T p.A1409S | Missense Mutation (SNP) | VAF 41/347 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CR2 | c.2965T>A p.F989I | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRACR2A | c.1689G>T p.R563S | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CRISP3 | c.661C>G p.P221A (on ENST00000371159 / NM_001368123.1; = p.P203A on NM_006061.4) | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.047); called by muse, varscan2
- CSH1 | c.486del p.Q163Rfs*63 | Frame Shift Del (DEL) | VAF 74/327 reads (23%) | called by mutect2, pindel, varscan2
- CSMD1 | c.1291C>G p.Q431E (on ENST00000520002; = p.Q430E on NM_033225.6) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CSNK2A1 | c.768C>G p.D256E | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CSRNP3 | c.1644delinsAG p.N548Kfs*3 | Frame Shift Ins (INS) | VAF 28/242 reads (12%) | called by pindel, varscan2*
- CTNND1 | c.2723A>G p.N908S (on ENST00000399050 / NM_001085458.2; = p.N881S on NM_001331.3) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CTSG | c.6G>T p.Q2H | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CTXN2 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CYP4F2 | c.1053G>T p.Q351H | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DBR1 | c.1315A>T p.S439C | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- DCAF8L1 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 27/190 reads (14%) | called by muse, mutect2, varscan2
- DCDC1 | c.2483C>A p.P828H | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DCHS2 | c.1612C>A p.L538I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.199); called by muse, mutect2
- DDC | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 94/449 reads (21%) | called by muse, mutect2, varscan2
- DDHD2 | c.1721-1G>T p.X574_splice | Splice Site (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- DDX56 | c.1294-1G>T p.X432_splice | Splice Site (SNP) | VAF 33/173 reads (19%) | called by muse, mutect2, varscan2
- DENND2D | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- DEPDC1 | c.977A>T p.Q326L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DHRS9 | c.921G>T p.L307F | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2
- DIAPH1 | c.1663C>G p.L555V | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, varscan2
- DIS3 | c.1727A>T p.K576M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DKKL1 | c.310del p.L104Sfs*6 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- DMRTB1 | c.340C>A p.R114S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DMXL1 | c.1804A>T p.K602* | Nonsense Mutation (SNP) | VAF 14/177 reads (8%) | called by muse, mutect2
- DNAJB11 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNMT3B | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- DOCK2 | c.5198C>A p.T1733N | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DOCK3 | c.4493G>A p.R1498K | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DSE | c.2877G>T p.*959Yext*2 | Nonstop Mutation (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- DSG1 | c.1501A>C p.T501P | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- DTL | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2
- DUSP6 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- DYNC1H1 | c.13748C>A p.T4583N | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- DYNC2H1 | c.8821G>T p.V2941L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DYSF | c.638T>A p.L213Q | Missense Mutation (SNP) | VAF 75/383 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EDA | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- EFCAB8 | c.758+1G>A p.X253_splice | Splice Site (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- EHD3 | c.1148A>T p.D383V | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- ELF2 | c.1334C>T p.S445F (on ENST00000379550 / NM_001331036.2; = p.S385F on NM_006874.4) | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2
- ELK1 | c.232G>C p.G78R | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELMOD3 | c.685A>T p.K229* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- EMD | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.024); called by muse, mutect2
- ENDOD1 | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- EP400 | c.3185G>T p.G1062V | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EPS8L3 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.289); called by muse, mutect2
- F8 | c.2771G>T p.G924V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2
- F8 | c.1443+8G>T | Splice Region (SNP) | VAF 13/223 reads (6%) | called by muse, mutect2
- FAM187A | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM205A | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.098); called by mutect2, varscan2
- FAM47E-STBD1 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- FBN3 | c.5924A>T p.E1975V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- FBXL13 | c.215A>C p.K72T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FDFT1 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- FER1L5 | c.968-7T>C | Splice Region (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2, varscan2
- FGB | c.1429dup p.M477Nfs*21 | Frame Shift Ins (INS) | VAF 69/413 reads (17%) | called by mutect2, pindel, varscan2
- FGD1 | c.2777G>T p.C926F | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGD3 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FKBP1C | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 32/554 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- FLG | c.5473C>T p.Q1825* | Nonsense Mutation (SNP) | VAF 75/305 reads (25%) | called by muse, mutect2, varscan2
- FLNC | c.7141T>C p.Y2381H | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FRMPD3 | c.999-1G>A p.X333_splice | Splice Site (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2
- GABRA1 | c.1358C>A p.T453K | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GABRA2 | c.1284G>C p.L428F | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2
- GABRG2 | c.1271C>A p.P424Q (on ENST00000361925 / NM_001375343.1; = p.P384Q on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAL3ST3 | c.300C>A p.S100R | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- GALNT9 | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GAPDHS | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GATB | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- GBF1 | c.1096G>T p.D366Y (on ENST00000369983 / NM_001377137.1; = p.D365Y on NM_004193.3) | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- GCN1 | c.7219G>T p.A2407S | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GFER | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- GINS3 | c.519G>T p.R173S | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GJA10 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- GPC3 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 78/465 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR6 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- GPR78 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- GRM6 | c.1739G>A p.S580N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GSDMC | c.1489G>T p.G497W | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GSG1L2 | c.113T>A p.V38E | Missense Mutation (SNP) | VAF 95/314 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GTF3C1 | c.916G>T p.V306L | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GUCY2C | c.3107A>G p.K1036R | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GUCY2F | c.1110T>A p.N370K | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2
- HECA | c.336C>G p.D112E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HEPH | c.3094G>T p.V1032L (on ENST00000343002; = p.V765L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/340 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- HEY2 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIP1 | c.2738G>T p.S913I | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HIPK1 | c.563A>T p.N188I | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HK1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- HMCN1 | c.15722C>T p.P5241L | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HMGCLL1 | c.278A>T p.K93M | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- HTR2A | c.889C>G p.R297G | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- HYDIN | c.10408G>T p.G3470C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ICE1 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- IFIT5 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, mutect2
- IGFBP1 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-49 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 45/293 reads (15%) | called by muse, mutect2, varscan2
- IL17RA | c.1355G>T p.R452L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- IL37 | c.509del p.A170Gfs*20 | Frame Shift Del (DEL) | VAF 26/212 reads (12%) | called by mutect2, pindel, varscan2
- IL9R | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ILK | c.1105A>C p.N369H | Missense Mutation (SNP) | VAF 87/493 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INPP5D | c.1324A>T p.I442F (on ENST00000445964 / NM_001017915.3; = p.I441F on NM_005541.5) | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2
- INSRR | c.1152C>G p.I384M | Missense Mutation (SNP) | VAF 16/464 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ISM2 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ITGA1 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2
- ITGA11 | c.2798G>T p.S933I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ITGA11 | c.100C>G p.P34A | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGAD | c.2011T>C p.S671P | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ITGAX | c.1200G>T p.M400I | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITPKB | c.225G>T p.W75C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ITPR2 | c.4412C>G p.A1471G | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- JAK1 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- JAK3 | c.1776G>T p.M592I | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- JAKMIP1 | c.938A>T p.D313V | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- KCNA1 | c.1381A>G p.M461V | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNN4 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KHSRP | c.485G>T p.R162I | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KIAA1210 | c.1115C>A p.T372N | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2
- KIF2C | c.1627A>G p.K543E | Missense Mutation (SNP) | VAF 17/283 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KIF4A | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2
- KIF4A | c.2122G>T p.A708S | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- KIF5A | c.291+1G>T p.X97_splice | Splice Site (SNP) | VAF 34/404 reads (8%) | called by muse, mutect2
- KIR3DL1 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 91/436 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KLHDC8B | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- KRT17 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2
- KRT33B | c.832A>T p.T278S | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- KRT34 | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); called by muse, mutect2
- KRTAP20-2 | c.43T>A p.Y15N | Missense Mutation (SNP) | VAF 63/360 reads (18%) | PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- LAG3 | c.462G>T p.R154S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LAGE3 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2
- LAMB4 | c.1961T>C p.L654P | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- LDHC | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 48/329 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LGMN | c.674G>T p.R225M | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LGR4 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LHX5 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- LIPI | c.589C>G p.L197V | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- LPA | c.2926C>A p.P976T | Missense Mutation (SNP) | VAF 54/587 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2
- LPAR5 | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPP | c.1727T>A p.L576Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP2 | c.13051T>C p.C4351R | Missense Mutation (SNP) | VAF 98/478 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP2 | c.12395A>T p.Q4132L | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by muse, mutect2
- LRRC32 | c.771T>A p.H257Q | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC45 | c.1047G>T p.Q349H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- LSG1 | c.1063A>T p.R355W | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- LSM14A | c.1311T>G p.F437L | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2
- MAEL | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- MAGEC3 | c.1337C>A p.P446Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MAGEE1 | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEE1 | c.2104G>T p.G702C | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- MAGEF1 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- MAGI2 | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAML1 | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 10/283 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.383); called by muse, mutect2
- MAMLD1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 90/527 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- MAOB | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 24/247 reads (10%) | called by muse, mutect2
- MBD1 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2
- MCHR1 | c.1098C>G p.I366M | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED7 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- MICAL3 | c.4850T>A p.L1617Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); called by muse, varscan2
- MLLT6 | c.1619G>T p.S540I | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MMP9 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPO | c.288G>T p.M96I | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- MROH7 | c.7del p.L3* | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- MS4A1 | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 75/383 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- MSMO1 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 31/269 reads (12%) | called by muse, mutect2, varscan2
- MUC12 | c.13192G>C p.D4398H (on ENST00000379442; = p.D4255H on NM_001164462.1) | Missense Mutation (SNP) | VAF 16/343 reads (5%) | SIFT tolerated (0.27); called by muse, mutect2
- MUC13 | c.1262T>A p.L421Q | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.39124G>C p.V13042L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MUC16 | c.23353A>T p.K7785* | Nonsense Mutation (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- MUC17 | c.12107C>T p.T4036I | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC22 | c.1606A>G p.T536A | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.35); called by muse, mutect2
- MUC4 | c.14031G>T p.R4677S (on ENST00000463781 / NM_018406.7; = p.R441S on NM_004532.6) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.251); called by muse, varscan2
- MYH10 | c.5671G>A p.E1891K | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- MYH7 | c.4241T>C p.L1414P | Missense Mutation (SNP) | VAF 50/331 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO18B | c.6421A>T p.R2141W | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MYO18B | c.7550C>T p.S2517F | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1A | c.1052G>T p.S351I | Missense Mutation (SNP) | VAF 33/456 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- MYO9A | c.4164T>A p.D1388E | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); called by muse, mutect2
- MYT1L | c.1939A>T p.N647Y | Missense Mutation (SNP) | VAF 17/384 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2
- NACAD | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- NAV1 | c.4833G>C p.Q1611H | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- NBAS | c.4447C>T p.P1483S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.922); called by muse, mutect2
- NBEA | c.5987A>T p.D1996V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- NCAPD2 | c.647A>T p.N216I | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.951); called by muse, mutect2
- NCAPD3 | c.2451G>T p.Q817H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- NEB | c.433A>T p.K145* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- NHSL2 | c.1442G>A p.S481N (on ENST00000510661; = p.S847N on NM_001013627.2) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2
- NIBAN1 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NLGN4X | c.1717G>T p.G573C | Missense Mutation (SNP) | VAF 67/360 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP12 | c.2173C>A p.L725M | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP7 | c.1050G>T p.M350I | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- NOL4 | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 63/364 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- NOL4L | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); called by muse, mutect2
- NR1H4 | c.1388A>T p.E463V (on ENST00000551379 / NM_001206993.2; = p.E449V on NM_005123.4) | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- NSD1 | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2
- NTSR2 | c.1146del p.M383* | Frame Shift Del (DEL) | VAF 24/150 reads (16%) | called by mutect2, pindel, varscan2
- NUP188 | c.3388C>A p.R1130S | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUP98 | c.4109C>G p.S1370* (on ENST00000359171 / NM_001365126.1; = p.S1353* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/221 reads (6%) | called by muse, mutect2
- OMG | c.970T>A p.F324I | Missense Mutation (SNP) | VAF 14/470 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- OPLAH | c.3806C>T p.A1269V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR13C2 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR14A2 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2B11 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- OR2M2 | c.631G>T p.V211F | Missense Mutation (SNP) | VAF 28/533 reads (5%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.952); called by muse, mutect2
- OR2M3 | c.902T>A p.F301Y | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- OR3A1 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4C16 | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- OR4K2 | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- OR52N2 | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5H2 | c.183C>A p.H61Q | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- OR8I2 | c.535del p.D179Tfs*6 | Frame Shift Del (DEL) | VAF 27/240 reads (11%) | called by mutect2, varscan2*
- OTOGL | c.5786G>A p.C1929Y (on ENST00000547103; = p.C1920Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OVCH1 | c.3265-1G>T p.X1089_splice | Splice Site (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- PACS2 | c.2359A>T p.R787W | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAK5 | c.801G>T p.R267S | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PAPSS1 | c.69G>T p.Q23H | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PC | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PCDH10 | c.1541C>A p.T514N | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDH17 | c.1622A>T p.N541I | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PCDHA12 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE1B | c.1313A>T p.D438V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- PDE8B | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 105/531 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDZD4 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2
- PEX6 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PGBD1 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHKA1 | c.1703A>G p.H568R | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- PLEC | c.12645G>T p.E4215D (on ENST00000322810 / NM_201380.4; = p.E4105D on NM_000445.5) | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLOD1 | c.422A>T p.K141M | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- POLA1 | c.3638C>G p.A1213G | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.676); called by muse, mutect2
- POLR1B | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR3D | c.809A>T p.Q270L | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLRMT | c.1825G>T p.V609L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- POM121L2 | c.3047C>G p.S1016* | Nonsense Mutation (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- PON3 | c.680T>A p.V227D | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- POR | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPOX | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- PPP1R16B | c.509C>A p.P170Q | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRAMEF1 | c.1420T>A p.C474S | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PRAMEF20 | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 59/564 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PRDX6 | c.613G>T p.G205* | Nonsense Mutation (SNP) | VAF 35/234 reads (15%) | called by muse, mutect2, varscan2
- PRPS1 | c.625_626del p.G209Rfs*12 | Frame Shift Del (DEL) | VAF 52/294 reads (18%) | called by mutect2, pindel, varscan2
- PRR32 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRSS3 | c.46T>C p.S16P (on ENST00000361005 / NM_007343.4; = p.S124P on NM_002771.3) | Missense Mutation (SNP) | VAF 84/512 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); called by muse, varscan2
- PSMB8 | c.202G>T p.E68* (on ENST00000374882 / NM_148919.4; = p.E64* on NM_004159.5) | Nonsense Mutation (SNP) | VAF 86/590 reads (15%) | called by muse, mutect2, varscan2
- PTGIS | c.1206+1G>T p.X402_splice | Splice Site (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- PTPRB | c.3961G>T p.G1321C | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRS | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | called by mutect2, varscan2
- PTPRT | c.3202C>A p.Q1068K | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- RAB39A | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB6D | c.438A>C p.K146N | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.089); called by muse, mutect2
- RAI1 | c.740A>G p.H247R | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RAI14 | c.2823G>T p.E941D | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RANBP2 | c.4382A>T p.Q1461L | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- RBM46 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RNASE13 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- RNF128 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RNF165 | c.858G>T p.E286D | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RNF175 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- RREB1 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 58/381 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RRP12 | c.598G>C p.A200P | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- RSRC1 | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCNN1G | c.584A>T p.H195L | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SEC11C | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SEC63 | c.2213A>G p.D738G | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- SEL1L3 | c.2641G>T p.G881C | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SELENOO | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.471); called by muse, varscan2
- SETD5 | c.2484G>C p.L828F | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.116); called by muse, mutect2
- SEZ6L2 | c.1384G>A p.D462N (on ENST00000308713 / NM_001114099.3; = p.D392N on NM_012410.4) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.105); called by muse, mutect2
- SFMBT2 | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHD | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SHROOM4 | c.1650dup p.E551Rfs*4 | Frame Shift Ins (INS) | VAF 96/517 reads (19%) | called by mutect2, pindel, varscan2
- SI | c.3738G>T p.M1246I | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SIK3 | c.128G>A p.R43H (on ENST00000445177 / NM_001366686.2; = p.R49H on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.27); called by muse, mutect2, varscan2
- SIM1 | c.1886C>A p.P629Q | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.697); called by muse, mutect2
- SIM1 | c.1885C>A p.P629T | Missense Mutation (SNP) | VAF 28/375 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); called by muse, mutect2
- SIM1 | c.12_31del p.K4Nfs*2 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel
- SLC11A1 | c.512G>A p.W171* | Nonsense Mutation (SNP) | VAF 21/173 reads (12%) | called by muse, mutect2, varscan2
- SLC13A4 | c.538+1G>A p.X180_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- SLC22A10 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC22A12 | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC2A2 | c.972C>A p.Y324* | Nonsense Mutation (SNP) | VAF 42/279 reads (15%) | called by muse, mutect2, varscan2
- SLC2A5 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2
- SLC30A1 | c.522C>G p.D174E | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC33A1 | c.1219C>G p.P407A | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SLC52A3 | c.1198-1G>T p.X400_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2
- SLC7A10 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SLC8B1 | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC9A9 | c.1810A>G p.R604G | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK2 | c.1759G>T p.G587* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- SNAP25 | c.564C>A p.N188K | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SNX30 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SPATA31A3 | c.2809C>A p.Q937K | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.227); called by mutect2, varscan2
- SPATA31D1 | c.2176G>T p.E726* | Nonsense Mutation (SNP) | VAF 130/493 reads (26%) | called by muse, mutect2, varscan2
- SPOCK3 | c.839A>C p.K280T | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPTA1 | c.6587T>G p.L2196R | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SREBF1 | c.1451A>T p.D484V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SSTR5 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAB2 | c.4927G>T p.E1643* | Nonsense Mutation (SNP) | VAF 16/284 reads (6%) | called by muse, mutect2
- STK32B | c.1069A>C p.T357P | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.391); called by muse, mutect2
- STOX2 | c.2409G>T p.Q803H | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SULF2 | c.2445C>A p.S815R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- SWT1 | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2
- SYN1 | c.1691C>A p.T564N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SYN1 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TAB3 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 45/257 reads (18%) | called by muse, mutect2, varscan2
- TBC1D28 | c.497+1G>T p.X166_splice | Splice Site (SNP) | VAF 55/272 reads (20%) | called by muse, mutect2, varscan2
- TBCC | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- TBX22 | c.287T>A p.L96H | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCEAL3 | c.281C>A p.P94Q | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TDRD6 | c.3867G>T p.L1289F | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TDRD9 | c.3575A>T p.H1192L | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TECPR2 | c.1278del p.L427Sfs*32 | Frame Shift Del (DEL) | VAF 37/216 reads (17%) | called by mutect2, pindel, varscan2
- TENT5D | c.320G>C p.C107S | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TFAP2D | c.270C>A p.Y90* | Nonsense Mutation (SNP) | VAF 41/189 reads (22%) | called by muse, mutect2, varscan2
- TFAP2D | c.754_755insC p.I252Tfs*20 | Frame Shift Ins (INS) | VAF 17/105 reads (16%) | called by mutect2, pindel, varscan2
- THOP1 | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- THPO | c.643C>A p.Q215K (on ENST00000649095 / NM_001290003.1; = p.Q75K on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/398 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- THSD1 | c.603G>T p.W201C | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TINAG | c.321A>T p.E107D | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- TLR7 | c.1711C>A p.L571M | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TM9SF2 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- TMEM132C | c.1440C>A p.D480E | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TMEM165 | c.870G>C p.M290I | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.381); called by muse, mutect2
- TMEM225 | c.519C>A p.N173K | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMPRSS11F | c.681A>G p.I227M | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TMPRSS11F | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMTC4 | c.2214G>C p.K738N (on ENST00000376234 / NM_001350577.2; = p.K757N on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- TNFRSF10C | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TNFRSF14 | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNS2 | c.811A>T p.K271* (on ENST00000314250 / NM_170754.4; = p.K281* on NM_015319.2) | Nonsense Mutation (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- TPBG | c.611T>A p.L204Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAPPC12 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- TRAPPC8 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRAV30 | c.310T>A p.S104T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TREM1 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 68/500 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- TRERF1 | c.1752G>T p.M584I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- TRIM50 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TRPC4AP | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRPV4 | c.502G>T p.G168W | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TSPAN9 | c.565-1G>T p.X189_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- TTC34 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TUBAL3 | c.439A>T p.S147C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TUBAL3 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UFD1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- USH2A | c.3275A>T p.D1092V | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2
- USP17L7 | c.1347G>T p.E449D | Missense Mutation (SNP) | VAF 62/988 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2
- VIRMA | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- VN1R2 | c.327T>A p.Y109* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | called by muse, mutect2, varscan2
- VSX2 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- WWC1 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 119/362 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.7863G>T p.K2621N (on ENST00000628543; = p.K2796N on NM_152381.6) | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- YY1 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by muse, mutect2
- ZFYVE16 | c.913A>T p.S305C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ZNF23 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF318 | c.5569C>T p.P1857S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- ZNF541 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- ZNF559 | c.1066A>T p.K356* | Nonsense Mutation (SNP) | VAF 5/101 reads (5%) | called by muse, mutect2
- ZNF646 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- ZNF653 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF69 | c.1463A>G p.Y488C | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ZNF721 | c.2678C>T p.S893F (on ENST00000338977; = p.S905F on NM_133474.4) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ZNF735 | c.1090T>A p.C364S | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF875 | c.495C>G p.F165L | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- ZSCAN4 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2
- ZSWIM2 | c.674G>T p.R225I | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.278); called by muse, mutect2
- ABHD8 | c.1089G>T p.L363= | Silent (SNP) | VAF 22/156 reads (14%) | called by muse, mutect2, varscan2
- ACOT7 | c.312G>A p.L104= (on ENST00000377855 / NM_181864.3; = p.L94= on NM_007274.4) | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2
- ACTRT1 | c.981C>A p.P327= | Silent (SNP) | VAF 38/236 reads (16%) | catalogued as COSV100947767; called by muse, mutect2, varscan2
- ACVR1B | c.207C>T p.C69= | Silent (SNP) | VAF 52/233 reads (22%) | catalogued as rs1311839057; called by muse, mutect2, varscan2
- ADGRE3 | c.1254G>T p.L418= | Silent (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- AFF2 | c.2580T>A p.V860= | Silent (SNP) | VAF 27/229 reads (12%) | called by muse, mutect2, varscan2
- AGAP1 | c.264G>T p.V88= | Silent (SNP) | VAF 12/179 reads (7%) | called by muse, mutect2
- AIRE | c.1458G>T p.G486= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs774298250; called by muse, mutect2, varscan2
- ANK1 | c.1437C>A p.R479= | Silent (SNP) | VAF 58/527 reads (11%) | called by muse, mutect2, varscan2
- ANKUB1 | c.166C>T p.L56= | Silent (SNP) | VAF 24/217 reads (11%) | catalogued as rs1435651460; called by muse, mutect2, varscan2
- AOAH | c.1539G>A p.Q513= | Silent (SNP) | VAF 36/230 reads (16%) | called by muse, mutect2, varscan2
- APOB | c.2745T>A p.V915= | Silent (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- ASH1L | c.5571C>T p.P1857= | Silent (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- ASH1L | c.5400G>A p.V1800= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs1440742645; called by muse, mutect2, varscan2
- ATP6AP2 | c.732G>A p.L244= | Silent (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- ATP8A1 | c.603A>G p.P201= | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- BCORL1 | c.1542G>T p.S514= | Silent (SNP) | VAF 31/194 reads (16%) | catalogued as COSV54396060; called by muse, mutect2, varscan2
- BPIFB1 | c.1348T>C p.L450= | Silent (SNP) | VAF 48/214 reads (22%) | catalogued as rs1382026351; called by muse, mutect2, varscan2
- BRCA1 | c.1125A>G p.L375= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as rs1060504578; ClinVar: likely benign; called by muse, mutect2, varscan2
- C2orf16 | c.5085C>G p.R1695= | Silent (SNP) | VAF 52/421 reads (12%) | called by muse, mutect2, varscan2
- CACNA1E | c.6768G>T p.V2256= (on ENST00000367573 / NM_001205293.3; = p.V2213= on NM_000721.4) | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- CACNA1S | c.4023G>A p.E1341= | Silent (SNP) | VAF 50/307 reads (16%) | catalogued as rs753756026; called by muse, mutect2, varscan2
- CADPS2 | c.135G>T p.P45= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- CCDC146 | c.1167A>G p.L389= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs746879016; called by muse, mutect2, varscan2
- CCDC63 | c.1674G>A p.R558= | Silent (SNP) | VAF 54/201 reads (27%) | called by muse, mutect2, varscan2
- CD300LB | c.378G>A p.A126= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as rs1023360659, COSV100075589; called by muse, mutect2, varscan2
- CDH16 | c.894C>G p.A298= | Silent (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.1836C>T p.I612= | Silent (SNP) | VAF 65/401 reads (16%) | called by muse, mutect2, varscan2
- CFAP100 | c.858G>A p.K286= | Silent (SNP) | VAF 14/151 reads (9%) | catalogued as rs1228727819; called by muse, mutect2, varscan2
- CFP | c.1191T>A p.P397= | Silent (SNP) | VAF 51/280 reads (18%) | called by muse, mutect2, varscan2
- CHRNB2 | c.561G>A p.L187= | Silent (SNP) | VAF 14/316 reads (4%) | called by muse, mutect2
- CIB3 | c.96T>C p.Y32= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV54166657; called by muse, varscan2
- CLCN7 | c.1953G>A p.L651= | Silent (SNP) | VAF 23/253 reads (9%) | called by muse, mutect2
- COBL | c.1500G>A p.L500= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs1436589202; called by muse, mutect2, varscan2
- COL22A1 | c.1177C>A p.R393= | Silent (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- COL8A2 | c.42G>T p.L14= | Silent (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- CRLF3 | c.747C>G p.V249= | Silent (SNP) | VAF 24/329 reads (7%) | called by muse, mutect2
- CTHRC1 | c.513C>A p.P171= | Silent (SNP) | VAF 39/422 reads (9%) | called by muse, mutect2
- CUBN | c.4269G>T p.T1423= | Silent (SNP) | VAF 40/285 reads (14%) | catalogued as COSV64721437; called by muse, mutect2, varscan2
- DACT2 | c.1905G>T p.V635= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- DCAF8 | c.1263G>T p.G421= | Silent (SNP) | VAF 37/249 reads (15%) | called by muse, mutect2, varscan2
- DDX23 | c.960T>C p.Y320= | Silent (SNP) | VAF 20/190 reads (11%) | catalogued as COSV100339620; called by muse, mutect2, varscan2
- DDX43 | c.1380A>T p.S460= | Silent (SNP) | VAF 15/73 reads (21%) | called by muse, varscan2
- DDX60 | c.3633G>T p.V1211= | Silent (SNP) | VAF 36/260 reads (14%) | called by muse, mutect2, varscan2
- DLGAP3 | c.969T>C p.D323= | Silent (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- DLX6 | c.735G>T p.S245= | Silent (SNP) | VAF 40/402 reads (10%) | catalogued as COSV99142177; called by muse, mutect2, varscan2
- DNHD1 | c.5823A>G p.Q1941= | Silent (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- DNHD1 | c.11256G>A p.L3752= | Silent (SNP) | VAF 14/209 reads (7%) | called by muse, mutect2
- DPF1 | c.357C>A p.L119= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- ELP2 | c.1527C>G p.V509= | Silent (SNP) | VAF 11/278 reads (4%) | called by muse, mutect2
- EMILIN1 | c.1644C>A p.A548= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- EPHA3 | c.2277G>T p.V759= | Silent (SNP) | VAF 48/285 reads (17%) | called by muse, mutect2, varscan2
- EPHB1 | c.1938C>A p.I646= | Silent (SNP) | VAF 41/200 reads (21%) | catalogued as COSV67657692, COSV67663154; called by muse, mutect2, varscan2
- FAM47B | c.693G>A p.R231= | Silent (SNP) | VAF 49/266 reads (18%) | called by muse, mutect2, varscan2
- FASTKD1 | c.1863C>T p.A621= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- FAT3 | c.4548C>G p.G1516= | Silent (SNP) | VAF 40/206 reads (19%) | catalogued as COSV53071983; called by muse, mutect2, varscan2
- FBXO39 | c.921G>T p.P307= | Silent (SNP) | VAF 43/206 reads (21%) | catalogued as rs764013991, COSV58620917; called by muse, mutect2, varscan2
- FCER1A | c.570C>A p.L190= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV63667496; called by muse, mutect2
- FCRL2 | c.456G>A p.L152= | Silent (SNP) | VAF 101/428 reads (24%) | called by muse, mutect2, varscan2
- FHL5 | c.564G>C p.L188= | Silent (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- FSIP2 | c.6795C>A p.A2265= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- GAK | c.2217G>T p.R739= | Silent (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- GBP5 | c.1461G>A p.K487= | Silent (SNP) | VAF 18/328 reads (5%) | called by muse, mutect2
- GORASP1 | c.97C>T p.L33= | Silent (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- GPAT2 | c.1608C>G p.L536= | Silent (SNP) | VAF 10/256 reads (4%) | catalogued as COSV100853350; called by muse, mutect2
- GPC4 | c.828C>A p.G276= | Silent (SNP) | VAF 34/212 reads (16%) | called by muse, mutect2, varscan2
- GPRC5D | c.984G>A p.E328= | Silent (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- GRID2 | c.2850T>C p.S950= | Silent (SNP) | VAF 28/208 reads (13%) | called by muse, mutect2, varscan2
- GRM5 | c.3123G>T p.S1041= (on ENST00000305447 / NM_001143831.2; = p.S1009= on NM_000842.4) | Silent (SNP) | VAF 24/174 reads (14%) | catalogued as rs1012015295; called by muse, mutect2, varscan2
- HYAL2 | c.603C>T p.H201= | Silent (SNP) | VAF 31/147 reads (21%) | catalogued as rs1553716289; called by muse, mutect2, varscan2
- HYAL4 | c.1278G>T p.L426= | Silent (SNP) | VAF 27/210 reads (13%) | called by muse, mutect2, varscan2
- IGSF8 | c.1410C>T p.P470= | Silent (SNP) | VAF 25/180 reads (14%) | called by muse, mutect2, varscan2
- IQSEC3 | c.777C>T p.S259= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- IQSEC3 | c.2478G>T p.L826= (on ENST00000538872 / NM_001170738.2; = p.L523= on NM_015232.1) | Silent (SNP) | VAF 36/173 reads (21%) | catalogued as rs1555096381; called by muse, mutect2, varscan2
- IRF8 | c.993G>C p.L331= | Silent (SNP) | VAF 63/362 reads (17%) | called by muse, mutect2, varscan2
- ITGAL | c.1221C>A p.T407= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs768669649; called by muse, mutect2
- ITGBL1 | c.798G>C p.G266= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as COSV101095466; called by muse, mutect2, varscan2
- KCNH8 | c.138C>A p.S46= | Silent (SNP) | VAF 51/243 reads (21%) | called by muse, mutect2, varscan2
- KCNT2 | c.3321G>T p.L1107= | Silent (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- KIAA1109 | c.14715T>C p.D4905= | Silent (SNP) | VAF 13/204 reads (6%) | called by muse, mutect2
- KIAA1210 | c.2514C>A p.S838= | Silent (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- KIAA1549L | c.3087G>A p.V1029= (on ENST00000321505; = p.V1326= on NM_012194.3) | Silent (SNP) | VAF 46/233 reads (20%) | called by muse, mutect2, varscan2
- KIF2B | c.627G>T p.P209= | Silent (SNP) | VAF 9/148 reads (6%) | catalogued as rs1344369419, COSV52130240, COSV99275032; called by muse, mutect2
- KLHL30 | c.444G>A p.L148= | Silent (SNP) | VAF 18/112 reads (16%) | called by muse, varscan2
- KLK7 | c.6A>T p.A2= | Silent (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- KMT2D | c.14898G>T p.R4966= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- KRT7 | c.318C>T p.I106= | Silent (SNP) | VAF 9/239 reads (4%) | called by muse, mutect2
- LAMA2 | c.7683C>A p.G2561= | Silent (SNP) | VAF 23/324 reads (7%) | called by muse, mutect2
- LAMB3 | c.2268G>T p.A756= | Silent (SNP) | VAF 68/383 reads (18%) | called by muse, mutect2, varscan2
- LGALS9B | c.288G>C p.G96= | Silent (SNP) | VAF 17/328 reads (5%) | called by muse, mutect2
- LIG1 | c.1296G>C p.V432= | Silent (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- LILRB1 | c.1977C>A p.A659= (on ENST00000427581; = p.A608= on NM_006669.6) | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV61117428; called by muse, mutect2, varscan2
- LMTK3 | c.2649G>A p.R883= | Silent (SNP) | VAF 44/240 reads (18%) | called by muse, mutect2, varscan2
- LOXHD1 | c.4800C>A p.A1600= | Silent (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1296C>A p.L432= | Silent (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- LSM1 | c.288A>G p.L96= | Silent (SNP) | VAF 64/288 reads (22%) | catalogued as rs773956422; called by muse, mutect2, varscan2
- MAF1 | c.189G>A p.Q63= | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- MATN3 | c.411C>A p.L137= | Silent (SNP) | VAF 46/290 reads (16%) | catalogued as COSV68099613; called by muse, mutect2, varscan2
- MME | c.1668A>T p.P556= | Silent (SNP) | VAF 82/545 reads (15%) | called by muse, mutect2, varscan2
- MOSPD1 | c.579G>T p.V193= | Silent (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
187 further variants in this file (0 protein-altering or splice-affecting, 78 silent, 109 other) are not listed here.
